Somatic mutation profile of tumor specimen MP2PRT-PAUCWZ-TMP1-A (aliquot MP2PRT-PAUCWZ-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUCWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (796 days).
Specimen MP2PRT-PAUCWZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be75da9b-a50a-4a2b-9a34-b3b780a7c346.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCWZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCWZ-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f989059-1fde-44ed-ae0f-ee1faa6c0090

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH18 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV56934961; called by muse, mutect2
- CSRNP3 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353543644, COSV58775303; called by muse, mutect2
- H3C7 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 17/393 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV55101191; called by muse, mutect2
- NPIPA1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 80/684 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.056); catalogued as rs774137205, COSV100047511, COSV60154015; called by muse, varscan2
- C1orf21 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- GPBP1 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- IGHV3-66 | chr14:106675012 GTGTCTCTCGCACAGTAATAC>ACCGGGG | Missense Mutation (DEL) | VAF 45/77 reads (58%) | called by pindel, varscan2*
- KIF4A | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2
- LCORL | c.4893C>G p.F1631L | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- MACF1 | c.7663G>C p.E2555Q | Missense Mutation (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- MED23 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2
- MRPL19 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- SFPQ | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 25/494 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2
- ZFHX4 | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ACSM2A | c.1644G>A p.L548= (on ENST00000219054; = p.L469= on NM_001308169.2) | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV99525603; called by muse, mutect2
- MUC16 | c.20859G>T p.L6953= | Silent (SNP) | VAF 67/186 reads (36%) | catalogued as COSV67459505, COSV67480947; called by muse, mutect2, varscan2
- NNT | c.909C>G p.L303= | Silent (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- PROKR1 | c.921C>T p.R307= | Silent (SNP) | VAF 105/287 reads (37%) | catalogued as rs759256884, COSV58136702; called by muse, mutect2, varscan2
- RBMXL3 | c.2373C>T p.S791= | Silent (SNP) | VAF 210/527 reads (40%) | catalogued as rs782669503; called by muse, mutect2
- HNRNPU | c.634+1011T>G | Intron (SNP) | VAF 117/292 reads (40%) | called by muse, mutect2, varscan2
